FM case AD15516 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Thyroid gland.
https://portal.gdc.cancer.gov/cases/31388812-24b3-46f2-b4fe-c767b77baa15

Male, 68.2 years: Papillary carcinoma, NOS (ICD-O-3 8050/3) of the thyroid gland; metastasis biopsied or resected from the pleura. Tumor nuclei on the sequenced sample's slide: 83% (pathologist estimate recorded by GDC). Sample type: Metastatic.
